Somatic mutation profile of tumor specimen 0DQ80X from CCDI case PBCEIH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Spinal cord; Age at diagnosis: 11.7 years (4,280 days).
Specimen 0DQ80X: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9623e3b5-dd11-44ed-bd23-aeb38184a690.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQ7W9 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3dd5a0c2-79ea-4913-bad8-57bd20e430f4

The open-access MAF lists 56 somatic variants for this specimen: 36 protein-altering or splice-affecting, 11 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 11, Intron 7, Splice Region 2, Splice Site 2, 5'UTR 1, Translation Start Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 118/335 reads (35%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.487T>G p.Y163D | Missense Mutation (SNP) | VAF 457/477 reads (96%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786203436, COSV52661160, COSV52676168, COSV52853225, COSV53025600; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ARHGAP27 | c.1845C>T p.S615= (on ENST00000428638 / NM_001282290.1; = p.S274= on NM_199282.3) | Splice Region (SNP) | VAF 11/353 reads (3%) | catalogued as rs1465333724; called by muse, mutect2
- C15orf39 | c.653A>C p.Q218P | Missense Mutation (SNP) | VAF 19/281 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.134); catalogued as rs752346892; called by muse, mutect2
- COL19A1 | c.1509G>C p.Q503H | Missense Mutation (SNP) | VAF 113/179 reads (63%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); catalogued as COSV100507664; called by muse, mutect2, varscan2
- COL5A1 | c.4201G>A p.E1401K | Missense Mutation (SNP) | VAF 203/432 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs1370262542, COSV100879366, COSV65668107; called by muse, mutect2, varscan2
- FYB1 | c.272G>C p.R91T | Missense Mutation (SNP) | VAF 73/514 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV60943424; called by muse, mutect2, varscan2
- IRS4 | c.2447G>A p.R816Q | Missense Mutation (SNP) | VAF 269/572 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs745412094; called by muse, mutect2, varscan2
- KEL | c.136A>G p.R46G | Missense Mutation (SNP) | VAF 18/512 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV62338203; called by muse, mutect2
- PCDHGB5 | c.686G>A p.R229Q | Missense Mutation (SNP) | VAF 26/382 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0.023); catalogued as rs779872602; called by muse, mutect2
- PRKG2 | c.454G>T p.D152Y | Missense Mutation (SNP) | VAF 120/261 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.379); catalogued as COSV52328957; called by muse, mutect2, varscan2
- RBMXL3 | c.2374G>A p.G792R | Missense Mutation (SNP) | VAF 23/698 reads (3%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.07); catalogued as rs782297888, COSV57750085; called by muse, mutect2
- RIPK2 | c.791G>A p.R264H | Missense Mutation (SNP) | VAF 152/386 reads (39%) | SIFT tolerated (0.45); PolyPhen benign (0.354); catalogued as rs766384952, COSV55133828; called by muse, mutect2, varscan2
- UBXN6 | c.1312G>A p.E438K | Missense Mutation (SNP) | VAF 151/340 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.041); catalogued as rs763974738; called by muse, mutect2, varscan2
- ADGRV1 | c.17767G>C p.A5923P | Missense Mutation (SNP) | VAF 16/352 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- ATG2A | c.334+6G>A | Splice Region (SNP) | VAF 19/703 reads (3%) | called by muse, mutect2
- BEND2 | c.1864C>G p.P622A | Missense Mutation (SNP) | VAF 30/578 reads (5%) | SIFT tolerated (0.71); PolyPhen benign (0.001); called by muse, mutect2
- BRD2 | c.1931A>G p.Y644C | Missense Mutation (SNP) | VAF 20/705 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- C18orf63 | c.709-1G>C p.X237_splice | Splice Site (SNP) | VAF 43/300 reads (14%) | called by muse, mutect2, varscan2
- C3 | c.4429G>A p.V1477I | Missense Mutation (SNP) | VAF 57/944 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); called by muse, mutect2
- C4orf54 | c.3068G>T p.R1023I | Missense Mutation (SNP) | VAF 127/316 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- CCDC114 | c.1130-2A>G p.X377_splice | Splice Site (SNP) | VAF 27/536 reads (5%) | called by muse, mutect2
- CHIC2 | c.454C>T p.L152F | Missense Mutation (SNP) | VAF 120/305 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- FPGT | c.761C>G p.A254G | Missense Mutation (SNP) | VAF 36/546 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.781); called by muse, mutect2
- FRG2 | c.480G>T p.R160S | Missense Mutation (SNP) | VAF 20/360 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.001); called by muse, mutect2
- IKBKE | c.2147T>C p.V716A | Missense Mutation (SNP) | VAF 134/391 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2
- MYF6 | c.409G>A p.A137T | Missense Mutation (SNP) | VAF 22/364 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- NBPF4 | c.1837G>A p.A613T | Missense Mutation (SNP) | VAF 258/797 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.604); called by muse, mutect2, varscan2
- PCDHGC3 | c.2411A>G p.E804G | Missense Mutation (SNP) | VAF 26/351 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.095); called by muse, mutect2
- PNMA6E | c.1018T>C p.W340R (on ENST00000445091 / NM_001367770.1; = p.W62R on NM_001351293.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/878 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2
- POLH | c.983A>G p.K328R | Missense Mutation (SNP) | VAF 30/650 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.024); called by muse, mutect2
- PTGFR | c.136C>A p.L46I | Missense Mutation (SNP) | VAF 76/798 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.917); called by muse, mutect2
- SH3GLB1 | c.775T>G p.Y259D | Missense Mutation (SNP) | VAF 34/596 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2
- SLC35F2 | c.947G>T p.G316V | Missense Mutation (SNP) | VAF 20/334 reads (6%) | SIFT tolerated (0.41); PolyPhen benign (0.042); called by muse, mutect2
- SPATA21 | c.1246G>A p.V416I | Missense Mutation (SNP) | VAF 17/541 reads (3%) | SIFT tolerated (0.1); PolyPhen benign (0.02); called by muse, mutect2
- SPI1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 15/504 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.23); called by muse, mutect2
- AHNAK2 | c.10776G>T p.V3592= | Silent (SNP) | VAF 27/206 reads (13%) | catalogued as COSV60933649; called by muse, mutect2, varscan2
- ALPK1 | c.3039T>A p.A1013= | Silent (SNP) | VAF 16/483 reads (3%) | called by muse, mutect2
- CCDC33 | c.1647G>A p.A549= | Silent (SNP) | VAF 120/305 reads (39%) | catalogued as rs754436063; called by muse, mutect2, varscan2
- DCAF12L1 | c.690T>A p.T230= | Silent (SNP) | VAF 231/451 reads (51%) | called by muse, mutect2, varscan2
- HIP1R | c.849C>T p.P283= | Silent (SNP) | VAF 38/622 reads (6%) | catalogued as rs200261764, COSV99458829; called by muse, mutect2
- LORICRIN | c.549C>T p.G183= | Silent (SNP) | VAF 191/481 reads (40%) | catalogued as rs1037958925; called by muse, mutect2, varscan2
- LRRN3 | c.69A>G p.V23= | Silent (SNP) | VAF 43/568 reads (8%) | called by muse, mutect2
- MAGEE1 | c.2379C>A p.T793= | Silent (SNP) | VAF 289/633 reads (46%) | catalogued as rs782409119; called by muse, mutect2, varscan2
- PLXND1 | c.4359C>T p.H1453= | Silent (SNP) | VAF 296/608 reads (49%) | catalogued as rs780259165; called by muse, mutect2, varscan2
- PSME4 | c.3223T>C p.L1075= | Silent (SNP) | VAF 200/474 reads (42%) | catalogued as rs376753235; called by muse, mutect2, varscan2
- SBSN | c.1137C>T p.A379= | Silent (SNP) | VAF 34/402 reads (8%) | called by muse, mutect2
- AP1G1 | c.643-23T>C | Intron (SNP) | VAF 51/172 reads (30%) | called by muse, mutect2, varscan2
- C19orf18 | c.*32A>G | 3'UTR (SNP) | VAF 11/230 reads (5%) | called by muse, mutect2
- CARD8 | c.392-60C>T | Intron (SNP) | VAF 8/60 reads (13%) | catalogued as rs1042266134; called by muse, mutect2, varscan2
- KLF8 | c.646+66T>A | Intron (SNP) | VAF 10/69 reads (14%) | called by muse, mutect2, varscan2
- KRT23 | c.1142+53G>A | Intron (SNP) | VAF 33/482 reads (7%) | called by muse, mutect2
- RBM19 | c.1939-68G>C | Intron (SNP) | VAF 16/199 reads (8%) | called by muse, mutect2
- SLC16A6 | c.233-87A>G | Intron (SNP) | VAF 78/161 reads (48%) | catalogued as rs1352840619; called by muse, mutect2, varscan2
- SLC25A14 | c.719+85G>T | Intron (SNP) | VAF 28/402 reads (7%) | catalogued as COSV99502266; called by muse, mutect2
- TCTE3 | c.-85G>A | 5'UTR (SNP) | VAF 28/141 reads (20%) | catalogued as rs1034389125; called by muse, mutect2, varscan2
